TCGA case TCGA-MQ-A6BL — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: Washington University - NYU. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0c8bd0eb-9c26-4fb0-a365-26354129f0da

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 78 years; Vital status: Dead; Days to death: 333 days.

Diagnoses (2)
1. Mesothelioma, biphasic, malignant (the primary disease): ICD-O-3 morphology code: 9053/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 78.3 years (28,590 days); Year of diagnosis: 2007; Method of diagnosis: Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Pemetrexed Disodium; Days to treatment start: 26 days; Days to treatment end: 144 days.
   Recorded as not given: Pleurodesis, NOS, prior to procurement; adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Mesothelioma, biphasic, malignant), site: Long bones of upper limb, scapula and associated joints. Age at diagnosis: 78.8 years (28,776 days); Days to diagnosis: 186 days; Prior treatment: Yes.

Follow-up (2 entries)
- Day 186 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Long bones of upper limb, scapula and associated joints; Days to progression: 186 days.
- Follow-up contact recording only the day: day 333.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-MQ-A6BL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 20 mg.
  Slide TCGA-MQ-A6BL-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 5; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-MQ-A6BL-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-MQ-A6BL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Biphasic mesothelioma.
- Drug treatment 2: Pharmaceutical therapy drug name: Alimta.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 333 days; disease-specific survival: event status not recorded, 333 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 186 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-MQ-A6BL-01A-11D-A34B-01): tumor purity 0.29, ploidy 1.8, whole-genome doublings 0.
